Somatic mutation profile of tumor specimen TCGA-EB-A97M-01A (aliquot TCGA-EB-A97M-01A-11D-A38G-08) from TCGA case TCGA-EB-A97M, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 66.3 years (24,228 days).
Specimen TCGA-EB-A97M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 17631dd6-cb92-430f-adb7-179a8a739a37.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A97M-10A (Blood Derived Normal), aliquot TCGA-EB-A97M-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/36477dc1-9ca7-409f-a418-aa1e27de6587

The open-access MAF lists 370 somatic variants for this specimen: 237 protein-altering or splice-affecting, 124 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 219, Silent 124, Nonsense Mutation 10, Splice Region 6, Intron 5, RNA 2, 3'Flank 2, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL4A3 | c.3230G>A p.G1077D | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1559909384, CM1413856, COSV100516657; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AARS1 | c.907C>T p.R303W | Missense Mutation (SNP) | VAF 77/202 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1302363015, COSV99933223; called by muse, mutect2, varscan2
- AC109583.1 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.337); catalogued as rs944176654, COSV100167774; called by muse, mutect2, varscan2
- ACTL9 | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.222); catalogued as COSV100185128; called by muse, mutect2, varscan2
- ADAM18 | c.791T>G p.L264R | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV99694932; called by muse, mutect2, varscan2
- ADAMTS10 | c.2531G>A p.G844D | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV99546488; called by muse, mutect2, varscan2
- ADGRB3 | c.4336C>T p.Q1446* | Nonsense Mutation (SNP) | VAF 16/38 reads (42%) | catalogued as COSV99483724; called by muse, mutect2, varscan2
- ADGRG5 | c.93G>A p.M31I | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.058); catalogued as COSV61083613; called by muse, mutect2
- ADH6 | c.355T>C p.S119P | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.686); catalogued as rs745595865, COSV99421976; called by muse, mutect2, varscan2
- AGT | c.385C>T p.H129Y | Missense Mutation (SNP) | VAF 128/212 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.092); catalogued as rs1021962354, COSV100794213; called by muse, mutect2, varscan2
- ALMS1 | c.12251G>A p.R4084K | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.693); catalogued as rs375314465, COSV100041220; called by muse, mutect2, varscan2
- AMBN | c.841G>A p.G281R | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as COSV100534269; called by muse, mutect2, varscan2
- ANGPT1 | c.823G>A p.G275R | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.025); catalogued as COSV99861982; called by muse, mutect2, varscan2
- ANTXR2 | c.1183C>T p.R395C | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761958936, COSV56313905; called by muse, mutect2, varscan2
- APC | c.7456C>T p.P2486S | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.542); catalogued as rs768537235, COSV99965499; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AQP9 | c.400G>A p.G134R | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99582629; called by muse, mutect2, varscan2
- ARFGEF2 | c.4555C>T p.P1519S | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs974721706, COSV100903999; called by muse, mutect2, varscan2
- ARHGEF5 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as rs564658226, COSV99282579; called by muse, mutect2, varscan2
- ARPP21 | c.171G>A p.K57= | Splice Region (SNP) | VAF 27/67 reads (40%) | catalogued as rs1359067189, COSV99491071; called by muse, mutect2, varscan2
- ARPP21 | c.2062G>A p.G688R | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as COSV51798213; called by muse, mutect2, varscan2
- ARPP21 | c.2063G>A p.G688E | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as rs762836472, COSV99491081; called by muse, mutect2, varscan2
- ASB4 | c.1268G>A p.G423E | Missense Mutation (SNP) | VAF 39/67 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57945543; called by muse, mutect2, varscan2
- ASXL3 | c.1513A>C p.M505L | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.813); catalogued as COSV99323543; called by muse, mutect2, varscan2
- ATP10A | c.472C>T p.R158* | Nonsense Mutation (SNP) | VAF 14/32 reads (44%) | catalogued as rs267604144, COSV63512941; called by muse, mutect2
- ATP2B2 | c.3107T>G p.V1036G (on ENST00000352432; = p.V1002G on NM_001683.5) | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100659676; called by muse, varscan2
- AURKC | c.343C>T p.R115W (on ENST00000302804 / NM_001015878.2; = p.R81W on NM_003160.3) | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs781258727, COSV100248733; called by muse, mutect2, varscan2
- BAIAP2 | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV100347517; called by muse, mutect2, varscan2
- BANK1 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV59843071; called by muse, mutect2, varscan2
- BAZ2B | c.628C>T p.R210* | Nonsense Mutation (SNP) | VAF 58/127 reads (46%) | catalogued as rs780189423, COSV58596651, COSV58605383; called by muse, mutect2, varscan2
- BCAM | c.983C>A p.T328N | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV99538517; called by muse, mutect2, varscan2
- BFAR | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0.158); catalogued as COSV99902022; called by muse, mutect2, varscan2
- BMPR1B | c.1231G>A p.A411T | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.189); catalogued as rs969503674, COSV99215393; called by muse, mutect2, varscan2
- BMPR1B | c.1232C>A p.A411D | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99215400; called by muse, mutect2, varscan2
- BRINP3 | c.134A>G p.D45G | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.977); catalogued as COSV66537924; called by muse, mutect2, varscan2
- C3orf20 | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 61/148 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.025); catalogued as rs760407677, COSV99513405; called by muse, mutect2, varscan2
- C4orf50 | c.745A>G p.R249G (on ENST00000324058; = p.R1481G on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/111 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100135605; called by muse, mutect2, varscan2
- C6 | c.1592G>A p.R531Q | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.243); catalogued as rs143506766; called by muse, mutect2, varscan2
- CABIN1 | c.2258A>T p.Y753F | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV99572745; called by muse, mutect2, varscan2
- CADM2 | c.520G>A p.E174K (on ENST00000407528 / NM_001167674.2; = p.E176K on NM_153184.4) | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.183); catalogued as COSV67367415, COSV67371063, COSV99081108; called by muse, mutect2, varscan2
- CALCRL | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV66475403; called by muse, mutect2, varscan2
- CAMKK1 | c.1219C>T p.P407S | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.326); catalogued as COSV99339970; called by muse, mutect2, varscan2
- CARD10 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1234420327, COSV52655661; called by muse, mutect2
- CCBE1 | c.935G>A p.G312E | Missense Mutation (SNP) | VAF 84/195 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as COSV67951695; called by muse, mutect2, varscan2
- CCDC158 | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.871); catalogued as rs968248934, COSV101187160; called by muse, mutect2, varscan2
- CCDC170 | c.1408C>T p.R470C | Missense Mutation (SNP) | VAF 35/43 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs267600858, COSV53337046; called by muse, mutect2, varscan2
- CCDC65 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.609); catalogued as rs535147502, COSV56739881; called by muse, mutect2, varscan2
- CD163 | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.88); catalogued as rs965223448, COSV100775715, COSV63129385; called by muse, mutect2, varscan2
- CD300E | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.78); PolyPhen benign (0.035); catalogued as COSV60790139; called by muse, mutect2, varscan2
- CDH5 | c.424C>T p.H142Y | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as COSV100439023, COSV58520218; called by muse, mutect2, varscan2
- CDON | c.3160C>T p.P1054S | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.1); catalogued as COSV99700646; called by muse, mutect2, varscan2
- CELF4 | c.997C>T p.P333S | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV100611146; called by muse, mutect2, varscan2
- CEMIP | c.2558G>A p.R853K | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs971035097, COSV99586138; called by muse, mutect2, varscan2
- CEP76 | c.1688C>G p.S563C | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); catalogued as COSV100042613; called by muse, mutect2, varscan2
- CFAP47 | c.4372G>A p.D1458N | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV100544976; called by muse, varscan2
- CGAS | c.1457C>T p.P486L | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1211647911, COSV64807837; called by muse, mutect2, varscan2
- CHD5 | c.3254G>A p.R1085K | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99312566; called by muse, mutect2, varscan2
- CIC | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV50706412, COSV99359022; called by muse, mutect2, varscan2
- CLDN17 | c.241C>G p.R81G | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99729012; called by muse, mutect2, varscan2
- CLEC14A | c.1276C>T p.H426Y | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV60561819; called by muse, mutect2, varscan2
- CNKSR1 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.819); catalogued as COSV100836676; called by muse, mutect2, varscan2
- COL19A1 | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.081); catalogued as rs970920114, COSV100505262; called by muse, mutect2, varscan2
- COL4A5 | c.4873C>T p.R1625C | Missense Mutation (SNP) | VAF 73/87 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs865842167, COSV60362202; called by muse, mutect2, varscan2
- COL9A1 | c.2656C>T p.P886S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); catalogued as COSV57879288; called by muse, varscan2
- CORIN | c.1694C>T p.S565L | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.065); catalogued as COSV56687152, COSV56688191; called by muse, mutect2, varscan2
- CPZ | c.1843G>A p.E615K (on ENST00000360986 / NM_001014447.3; = p.E604K on NM_003652.3) | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs775874480, COSV59923215; called by muse, mutect2, varscan2
- CREB3L3 | c.1079C>T p.S360F | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50174833; called by muse, mutect2, varscan2
- CTNND2 | c.3149C>T p.P1050L | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs754489153, COSV100472245; called by muse, mutect2, varscan2
- CYP19A1 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53058646; called by muse, mutect2, varscan2
- DAW1 | c.692G>A p.G231E | Missense Mutation (SNP) | VAF 64/148 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1050491432, COSV100005874; called by muse, mutect2, varscan2
- DGCR2 | c.1366C>T p.H456Y | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs758583945, COSV54221368; called by muse, mutect2, varscan2
- DMBT1 | c.5080G>A p.G1694S (on ENST00000338354 / NM_001377530.1; = p.G937S on NM_004406.3) | Missense Mutation (SNP) | VAF 124/178 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs560035067; called by muse, mutect2, varscan2
- DNAH17 | c.4307C>T p.T1436I | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs926634120, COSV101101520; called by muse, mutect2, varscan2
- DNAH5 | c.3502G>A p.E1168K | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.382); catalogued as COSV54219615; called by muse, mutect2, varscan2
- DSC2 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); catalogued as rs867026954, COSV99199488; called by muse, mutect2, varscan2
- DSG2 | c.1905C>G p.C635W | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV99852770; called by muse, mutect2, varscan2
- E2F4 | c.854G>C p.S285T | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as COSV100681432, COSV62607520; called by muse, varscan2
- EGFL8 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.097); catalogued as rs576566774, COSV61247503, COSV61248229; called by muse, mutect2, varscan2
- EMC10 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV100618408; called by muse, mutect2
- ESRRB | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.075); catalogued as COSV55068696; called by muse, mutect2, varscan2
- FAM78B | c.573G>A p.W191* | Nonsense Mutation (SNP) | VAF 30/190 reads (16%) | catalogued as COSV100597358; called by muse, mutect2, varscan2
- FLG2 | c.4031G>A p.R1344K | Missense Mutation (SNP) | VAF 30/281 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as COSV66167335, COSV66172461; called by muse, mutect2, varscan2
- FREM2 | c.5210G>A p.R1737K | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV99746963; called by muse, mutect2, varscan2
- FUT9 | c.402G>A p.M134I | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.593); catalogued as COSV56157390; called by muse, mutect2, varscan2
- GABRA2 | c.743G>A p.R248K | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100734590, COSV62911664; called by muse, mutect2, varscan2
- GAPT | c.346G>A p.G116R | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100576243; called by muse, mutect2, varscan2
- GBA3 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.118); catalogued as COSV72437959; called by muse, mutect2, varscan2
- GDF3 | c.476C>T p.T159I | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as COSV100325080; called by muse, mutect2, varscan2
- GFRAL | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.065); catalogued as COSV100474651; called by muse, mutect2, varscan2
- GFRAL | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV100475065, COSV61234494; called by muse, mutect2, varscan2
- GLB1 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.351); catalogued as COSV100256930; called by muse, mutect2, varscan2
- GLI2 | c.1469T>C p.F490S (on ENST00000361492 / NM_001374353.1; = p.F507S on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58040859; called by muse, mutect2, varscan2
- GLI2 | c.1470C>T p.F490= (on ENST00000361492 / NM_001374353.1; = p.F507= on NM_005270.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 20/52 reads (38%) | catalogued as rs544791528, COSV58035231; called by muse, mutect2, varscan2
- GLI2 | c.2266G>A p.G756S (on ENST00000361492 / NM_001374353.1; = p.G773S on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.035); catalogued as COSV100082426; called by muse, mutect2, varscan2
- GOLGA6A | c.1504G>A p.D502N | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as COSV99297010; called by muse, varscan2
- GOT2 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as rs1428801837, COSV99803456; called by muse, mutect2, varscan2
- GPX7 | c.365G>A p.G122D | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV100790891; called by muse, mutect2, varscan2
- GSDMC | c.143C>T p.S48L | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs765739292, COSV52694100; called by muse, mutect2, varscan2
- GUCY2C | c.2103G>A p.M701I | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV99663253; called by muse, mutect2, varscan2
- HECTD2 | c.1835A>T p.N612I | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99978170; called by muse, mutect2, varscan2
- HIVEP1 | c.4513C>T p.P1505S | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.329); catalogued as COSV101044742; called by muse, mutect2, varscan2
- HK1 | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 51/74 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV53854254; called by muse, mutect2, varscan2
- HP | c.851G>A p.W284* | Nonsense Mutation (SNP) | VAF 22/59 reads (37%) | catalogued as COSV100577459; called by muse, mutect2, varscan2
- HSPB8 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99931147; called by muse, mutect2, varscan2
- HTR6 | c.736G>A p.G246R | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV99229921; called by muse, mutect2, varscan2
- HYKK | c.589C>T p.R197* | Nonsense Mutation (SNP) | VAF 28/81 reads (35%) | catalogued as rs781696892, COSV66460443; called by muse, mutect2, varscan2
- IFT122 | c.1421G>A p.R474H (on ENST00000348417 / NM_052989.3; = p.R415H on NM_018262.4) | Missense Mutation (SNP) | VAF 31/45 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs753501616, COSV99958768; called by muse, mutect2, varscan2
- IGSF21 | c.1181G>A p.G394E | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99243803; called by muse, mutect2, varscan2
- IL16 | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.85); PolyPhen benign (0.056); catalogued as rs761512344, COSV100267030; called by muse, mutect2, varscan2
- IP6K3 | c.365C>T p.T122I | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1266715722, COSV99539591; called by muse, mutect2, varscan2
- IPO7 | c.2494C>T p.H832Y | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1202142948, COSV101121786; called by muse, mutect2, varscan2
- ITSN1 | c.1229A>T p.E410V | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as COSV101180443; called by muse, mutect2, varscan2
- KCNC2 | c.1856C>T p.S619L | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV100128256; called by muse, mutect2, varscan2
- KCNK16 | c.239G>C p.G80A | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100949075; called by muse, mutect2, varscan2
- KIAA1217 | c.2747C>T p.S916F | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV56821434; called by muse, mutect2, varscan2
- KIDINS220 | c.4420G>A p.D1474N | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99874988; called by muse, mutect2, varscan2
- KIF1A | c.1015G>A p.D339N | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV100239913; called by muse, mutect2, varscan2
- KLRK1 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.017); catalogued as COSV99555029; called by muse, mutect2, varscan2
- LAMA3 | c.9466G>A p.E3156K (on ENST00000313654 / NM_198129.4; = p.E1547K on NM_000227.6) | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99333966; called by muse, mutect2, varscan2
- LCA5 | c.782G>A p.R261K | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.95); PolyPhen benign (0.007); catalogued as COSV100878172; called by muse, mutect2, varscan2
- LILRA6 | c.677C>T p.S226F | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as COSV54443692, COSV99557151; called by muse, mutect2
- LRP2 | c.11986G>A p.E3996K | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754365114, COSV55548648; called by muse, mutect2, varscan2
- LRRC7 | c.724G>A p.D242N (on ENST00000651989 / NM_001370785.2; = p.D209N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 65/103 reads (63%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.686); catalogued as COSV99224658; called by muse, mutect2, varscan2
- LTBP3 | c.2959G>A p.G987S | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.578); catalogued as rs777330042, COSV99533781; called by muse, varscan2
- LTF | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as COSV99206903; called by muse, mutect2, varscan2
- LYST | c.11249C>T p.S3750L | Missense Mutation (SNP) | VAF 84/162 reads (52%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.78); catalogued as COSV101088295; called by muse, mutect2, varscan2
- MAGEC2 | c.785G>A p.R262K | Missense Mutation (SNP) | VAF 74/90 reads (82%) | SIFT tolerated (0.11); PolyPhen benign (0.055); catalogued as COSV99909413; called by muse, mutect2, varscan2
- MC3R | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 68/191 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs373127703; called by muse, mutect2, varscan2
- MDGA2 | c.1825C>T p.P609S (on ENST00000399232 / NM_001113498.2; = p.P311S on NM_182830.4) | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as rs377249612, COSV62115359; called by muse, mutect2, varscan2
- MDN1 | c.5833G>A p.E1945K | Missense Mutation (SNP) | VAF 89/235 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101020792; called by muse, mutect2, varscan2
- MROH7 | c.2110G>A p.G704R | Missense Mutation (SNP) | VAF 59/108 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59872076; called by muse, mutect2, varscan2
- MSR1 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 45/72 reads (63%) | SIFT tolerated (0.27); PolyPhen benign (0.045); catalogued as rs904659075, COSV50507610; called by muse, mutect2, varscan2
- MTMR6 | c.994G>A p.V332M | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766786838, COSV101110722; called by muse, mutect2, varscan2
- MYBPC1 | c.2132C>T p.P711L (on ENST00000550270 / NM_206820.2; = p.P736L on NM_002465.4) | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as COSV100637760; called by muse, mutect2, varscan2
- MYH8 | c.3905C>T p.S1302F | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs781047786, COSV101238224, COSV67965901; called by muse, mutect2, varscan2
- MYH8 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV101238225; called by muse, mutect2, varscan2
- MYLK3 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV101189057, COSV67366296; called by muse, mutect2, varscan2
- MYO7B | c.548C>T p.S183L | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as rs770751834, COSV67344446; called by muse, mutect2, varscan2
- MYOF | c.5773C>A p.P1925T | Missense Mutation (SNP) | VAF 89/127 reads (70%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100825259; called by muse, mutect2, varscan2
- NCCRP1 | c.399G>A p.L133= | Splice Region (SNP) | VAF 61/173 reads (35%) | catalogued as COSV100355747; called by muse, mutect2, varscan2
- NCCRP1 | c.400G>A p.G134S | Missense Mutation (SNP) | VAF 60/174 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV100355750; called by muse, mutect2, varscan2
- NCOA2 | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71763949; called by muse, mutect2, varscan2
- NEO1 | c.3728C>T p.S1243F | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99981316; called by muse, mutect2, varscan2
- NLRX1 | c.1678C>T p.P560S | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99423726; called by muse, mutect2, varscan2
- NRXN1 | c.980C>T p.S327L | Missense Mutation (SNP) | VAF 56/119 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs1351386294, CM1414134, COSV58438796; called by muse, mutect2, varscan2
- NRXN2 | c.3346G>A p.D1116N | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT tolerated (0.39); PolyPhen benign (0.031); catalogued as rs912107570, COSV55458969; called by muse, mutect2, varscan2
- NUMA1 | c.2071G>A p.E691K | Missense Mutation (SNP) | VAF 54/100 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100705823; called by muse, mutect2, varscan2
- NUP188 | c.3071C>T p.P1024L | Missense Mutation (SNP) | VAF 105/153 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101001206; called by muse, mutect2, varscan2
- NUP62 | c.1033G>C p.E345Q | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.588); catalogued as COSV100351799; called by muse, mutect2, varscan2
- ODF1 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.368); catalogued as rs769951903, COSV99574030; called by muse, mutect2, varscan2
- OOEP | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.356); catalogued as rs868133344, COSV64859087; called by muse, mutect2, varscan2
- OR10G7 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100389772; called by muse, mutect2, varscan2
- OR2F1 | c.202C>T p.L68F | Missense Mutation (SNP) | VAF 66/156 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs754242846, COSV101231286; called by muse, mutect2, varscan2
- OR51T1 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.938); catalogued as rs766869888, COSV100434300, COSV59026179; called by muse, mutect2, varscan2
- OR8B3 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV100660361; called by muse, mutect2, varscan2
- OXR1 | c.1585G>A p.E529K (on ENST00000442977 / NM_001198532.1; = p.E528K on NM_018002.3) | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.298); catalogued as COSV100366766; called by muse, mutect2, varscan2
- PCDHB2 | c.175G>A p.G59R | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.014); catalogued as COSV52038545; called by muse, mutect2, varscan2
- PCDHB5 | c.1322C>T p.S441F | Missense Mutation (SNP) | VAF 84/211 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as rs1361648914, COSV50660420, COSV50661708, COSV99167661; called by muse, mutect2, varscan2
- PCLO | c.9973A>T p.T3325S | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.173); catalogued as COSV100427694; called by muse, mutect2, varscan2
- PDE5A | c.1613G>A p.R538K | Missense Mutation (SNP) | VAF 90/223 reads (40%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV53352853; called by muse, mutect2, varscan2
- PDGFRB | c.1315C>T p.R439W | Missense Mutation (SNP) | VAF 75/159 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs1013933182, COSV55809411; called by muse, mutect2, varscan2
- PFKP | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 48/65 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101126943; called by muse, mutect2, varscan2
- PHACTR4 | c.236T>G p.V79G (on ENST00000373839 / NM_001350159.2; = p.V89G on NM_023923.4) | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100868401; called by muse, mutect2, varscan2
- PID1 | c.614A>G p.K205R (on ENST00000354069 / NM_001330156.1; = p.K203R on NM_017933.5) | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as COSV100819545; called by muse, varscan2
- PID1 | c.575C>T p.S192F (on ENST00000354069 / NM_001330156.1; = p.S190F on NM_017933.5) | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV62477417; called by muse, varscan2
- PIGF | c.21G>C p.K7N | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as rs1384589050, COSV99482676; called by muse, mutect2, varscan2
- PLCXD2 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.908); catalogued as COSV67342017; called by muse, mutect2, varscan2
- PLG | c.1643C>T p.P548L | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as COSV99804275; called by muse, mutect2, varscan2
- PLIN4 | c.125C>T p.A42V (on ENST00000301286; = p.A57V on NM_001367868.2) | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as rs1234557917, COSV100012775; called by muse, mutect2, varscan2
- POLR2A | c.1952C>T p.S651F | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs867128308; called by muse, mutect2, varscan2
- PREX2 | c.1569G>A p.Q523= | Splice Region (SNP) | VAF 35/110 reads (32%) | catalogued as COSV55790736; called by muse, mutect2, varscan2
- PRPF6 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53870101; called by muse, mutect2, varscan2
- PSG5 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 116/267 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.953); catalogued as COSV61653421; called by muse, mutect2, varscan2
- PTPN22 | c.732G>A p.W244* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | catalogued as COSV100703401; called by muse, mutect2
- PTPRD | c.3239C>T p.S1080L | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT tolerated (0.73); PolyPhen benign (0.015); catalogued as COSV61930009; called by muse, mutect2, varscan2
- PTPRK | c.4313C>T p.S1438L (on ENST00000368215 / NM_001291984.2; = p.S1439L on NM_002844.4) | Missense Mutation (SNP) | VAF 32/45 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV63909600; called by muse, mutect2, varscan2
- PTPRK | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 83/115 reads (72%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as rs983513819, COSV100950417; called by muse, mutect2, varscan2
- RABGAP1L | c.2380C>T p.Q794* | Nonsense Mutation (SNP) | VAF 46/66 reads (70%) | catalogued as COSV99268005; called by muse, mutect2, varscan2
- RCSD1 | c.890G>A p.G297E | Missense Mutation (SNP) | VAF 15/16 reads (94%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.678); catalogued as rs1172715962, COSV100827563; called by muse, mutect2, varscan2
- RDH8 | c.559G>A p.E187K (on ENST00000651512; = p.E167K on NM_015725.4) | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755753285, COSV50674103; called by muse, mutect2, varscan2
- RGS8 | c.227C>T p.T76M (on ENST00000367556 / NM_001369564.2; = p.T94M on NM_033345.3) | Missense Mutation (SNP) | VAF 116/383 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs759655284, COSV99276455; called by muse, mutect2, varscan2
- RNF138 | c.449G>C p.S150T | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as COSV99857362; called by muse, mutect2, varscan2
- RNF180 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1159729079, COSV99684381, COSV99684583; called by muse, mutect2
- RPL27 | c.233A>G p.N78S | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.14); catalogued as rs1175460441, COSV99518435; called by muse, mutect2, varscan2
- RPTOR | c.3737C>T p.S1246L | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV60805812; called by muse, mutect2, varscan2
- RTL9 | c.3895G>A p.E1299K | Missense Mutation (SNP) | VAF 68/80 reads (85%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV101511627; called by muse, mutect2, varscan2
- SCN11A | c.3424G>A p.E1142K | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as rs1189579972, COSV100181003; called by muse, mutect2, varscan2
- SCRN2 | c.1027C>T p.R343W | Missense Mutation (SNP) | VAF 60/116 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs767158187, COSV51635667; called by muse, mutect2, varscan2
- SERPINC1 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 132/182 reads (73%) | SIFT tolerated (0.69); PolyPhen benign (0.08); catalogued as CM113644, COSV62928951; called by muse, mutect2
- SIGLEC12 | c.247C>T p.R83* | Nonsense Mutation (SNP) | VAF 48/135 reads (36%) | catalogued as rs749952086, COSV52461771; called by muse, mutect2, varscan2
- SLC30A8 | c.869T>C p.L290P | Missense Mutation (SNP) | VAF 61/191 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.637); catalogued as rs867484704, COSV69977486; called by muse, mutect2, varscan2
- SLC32A1 | c.896T>G p.F299C | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99461804; called by muse, mutect2, varscan2
- SLC4A10 | c.2204C>T p.S735F (on ENST00000446997 / NM_001354461.2; = p.S705F on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV55766890; called by muse, mutect2, varscan2
- SLC5A11 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 75/186 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.062); catalogued as rs772580414, COSV61741008; called by muse, mutect2, varscan2
- SLC5A7 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV50889441; called by muse, mutect2, varscan2
- SLC6A9 | c.775C>T p.L259F (on ENST00000360584 / NM_201649.4; = p.L205F on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT tolerated (0.58); PolyPhen benign (0.011); catalogued as COSV100746051; called by muse, mutect2, varscan2
- SLC8A3 | c.2096G>A p.R699K (on ENST00000381269 / NM_183002.3; = p.R697K on NM_033262.4) | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.933); catalogued as rs1379959500, COSV53691367, COSV99385498; called by muse, mutect2, varscan2
- SLCO1B3 | c.1633T>C p.S545P | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.824); catalogued as COSV99680831; called by muse, mutect2
- SLCO1C1 | c.1763C>T p.A588V | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99858514; called by muse, mutect2, varscan2
- SPTBN5 | c.4813G>A p.E1605K | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.331); catalogued as COSV100310716; called by muse, mutect2, varscan2
- SULT1C3 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.081); catalogued as COSV100227329, COSV104411586; called by mutect2, varscan2
- SUN5 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as rs746468014, COSV62181084, COSV62181720; called by muse, mutect2, varscan2
- SYT1 | c.382T>A p.L128M | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.028); catalogued as COSV99693891; called by muse, mutect2, varscan2
- TAPBPL | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99868956; called by muse, mutect2, varscan2
- TBC1D4 | c.1188T>G p.D396E | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66487842; called by muse, mutect2, varscan2
- TEK | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 24/30 reads (80%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV101193177; called by muse, mutect2, varscan2
- TICAM1 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.078); catalogued as COSV99940992; called by muse, mutect2, varscan2
- TJAP1 | c.582G>A p.L194= (on ENST00000372445 / NM_001146016.1; = p.L184= on NM_080604.3) | Splice Region (SNP) | VAF 76/185 reads (41%) | catalogued as COSV99446184; called by muse, mutect2, varscan2
- TMC5 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 112/261 reads (43%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as rs369805960; called by muse, mutect2, varscan2
- TNC | c.1976C>T p.T659I | Missense Mutation (SNP) | VAF 37/52 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60781445; called by muse, mutect2, varscan2
- TNFAIP8L3 | c.845G>A p.G282E | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100552432; called by muse, mutect2, varscan2
- TRERF1 | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as COSV61675215; called by muse, mutect2, varscan2
- TRPC4 | c.1294G>A p.D432N | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.989); catalogued as COSV59010004; called by muse, mutect2, varscan2
- TSKU | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs368367731; called by muse, mutect2
- TSPOAP1 | c.5231C>T p.S1744L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99270130, COSV99272298; called by muse, mutect2, varscan2
- TTN | c.65494G>A p.E21832K (on ENST00000591111; = p.E14408K on NM_003319.4) | Missense Mutation (SNP) | VAF 42/87 reads (48%) | PolyPhen probably damaging (0.997); catalogued as COSV100595671; called by muse, varscan2
- TTN | c.23135C>T p.P7712L (on ENST00000591111; = p.P6785L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/172 reads (34%) | PolyPhen benign (0.053); catalogued as COSV100595673; called by muse, mutect2, varscan2
- TTN | c.5815C>T p.L1939F (on ENST00000591111; = p.L1893F on NM_003319.4) | Missense Mutation (SNP) | VAF 63/170 reads (37%) | PolyPhen probably damaging (0.999); catalogued as rs1459261528, COSV60221324; called by muse, mutect2, varscan2
- USP43 | c.2273C>T p.P758L | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV99556388; called by muse, mutect2, varscan2
- VEZT | c.707del p.T236Nfs*31 | Frame Shift Del (DEL) | VAF 26/62 reads (42%) | catalogued as COSV54144941; called by mutect2, pindel*, varscan2
- VPS13D | c.12427G>A p.G4143S | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.674); catalogued as COSV99165515; called by muse, mutect2, varscan2
- VPS54 | c.2829G>A p.G943= | Splice Region (SNP) | VAF 28/71 reads (39%) | catalogued as COSV99707769; called by muse, mutect2, varscan2
- WDR11 | c.2662C>T p.Q888* | Nonsense Mutation (SNP) | VAF 23/28 reads (82%) | catalogued as COSV99676268; called by muse, mutect2, varscan2
- WDR33 | c.3217C>T p.P1073S | Missense Mutation (SNP) | VAF 61/138 reads (44%) | SIFT tolerated, low confidence (0.33); PolyPhen probably damaging (0.968); catalogued as rs145945303; called by muse, mutect2, varscan2
- WIPF2 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 91/195 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.154); catalogued as COSV100063323; called by muse, mutect2, varscan2
- WNK3 | c.5266G>A p.G1756R | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100670835; called by muse, mutect2, varscan2
- ZBTB4 | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV100262785; called by muse, mutect2, varscan2
- ZBTB44 | c.253C>T p.L85F | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100777226; called by muse, mutect2, varscan2
- ZFHX4 | c.8762C>T p.S2921F | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.879); catalogued as COSV50668803, COSV51485248; called by muse, mutect2, varscan2
- ZNF24 | c.550C>T p.H184Y | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.775); catalogued as COSV99734191; called by muse, mutect2, varscan2
- ZNF318 | c.958C>T p.L320F | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1303028729, COSV100545960; called by muse, mutect2, varscan2
- ZNF334 | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV100748981; called by muse, mutect2, varscan2
- ZNF347 | c.158A>T p.D53V | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV100498141; called by muse, mutect2, varscan2
- ZNF404 | c.1213C>T p.H405Y | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100182314; called by muse, mutect2
- ZNF804A | c.2458C>T p.H820Y | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs750860993, COSV56449928; called by muse, mutect2, varscan2
- ZNF821 | c.215C>T p.S72F (on ENST00000425432 / NM_001376297.1; = p.S30F on NM_017530.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); catalogued as COSV100546711; called by muse, mutect2, varscan2
- KMT2B | c.4664dup p.P1556Afs*122 | Frame Shift Ins (INS) | VAF 9/41 reads (22%) | called by mutect2, pindel, varscan2
- POTEM | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- A2ML1 | c.2247G>A p.K749= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV55291557, COSV55296051; called by muse, mutect2, varscan2
- ABRAXAS2 | c.1209C>T p.P403= | Silent (SNP) | VAF 23/28 reads (82%) | catalogued as rs780509827, COSV100044835; called by muse, mutect2, varscan2
- ACAP1 | c.894G>A p.Q298= | Silent (SNP) | VAF 62/155 reads (40%) | catalogued as COSV50135258; called by muse, mutect2, varscan2
- ACTN4 | c.262C>T p.L88= | Silent (SNP) | VAF 40/81 reads (49%) | catalogued as COSV99399803; called by muse, mutect2, varscan2
- ADGRE1 | c.777C>T p.F259= | Silent (SNP) | VAF 43/102 reads (42%) | catalogued as COSV99165048; called by muse, mutect2, varscan2
- ADGRF2 | c.1347C>T p.I449= (on ENST00000296862 / NM_001368115.2; = p.I381= on NM_153839.7) | Silent (SNP) | VAF 67/167 reads (40%) | catalogued as rs755951692, COSV99730739; called by muse, mutect2, varscan2
- AGO3 | c.577C>T p.L193= | Silent (SNP) | VAF 21/103 reads (20%) | catalogued as COSV55794884; called by muse, mutect2, varscan2
- AGT | c.384C>T p.V128= | Silent (SNP) | VAF 128/211 reads (61%) | catalogued as COSV100794215; called by muse, mutect2, varscan2
- ALDH2 | c.1275G>C p.L425= | Silent (SNP) | VAF 26/48 reads (54%) | catalogued as COSV99922735; called by muse, mutect2, varscan2
- ANPEP | c.870G>A p.V290= | Silent (SNP) | VAF 49/112 reads (44%) | catalogued as COSV55590971; called by muse, mutect2, varscan2
- ATP10D | c.3693C>T p.P1231= | Silent (SNP) | VAF 15/155 reads (10%) | catalogued as COSV99905179; called by muse, mutect2, varscan2
- ATP2A3 | c.2280C>T p.F760= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV99988819; called by muse, mutect2, varscan2
- ATP7B | c.225C>T p.S75= | Silent (SNP) | VAF 35/88 reads (40%) | catalogued as rs1218959048, COSV99666075; called by muse, mutect2, varscan2
- AURKC | c.342C>T p.R114= (on ENST00000302804 / NM_001015878.2; = p.R80= on NM_003160.3) | Silent (SNP) | VAF 38/104 reads (37%) | catalogued as rs1568484157, COSV100248727; called by muse, mutect2, varscan2
- BANP | c.52C>T p.L18= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV99620815, COSV99621523; called by muse, mutect2, varscan2
- BMP7 | c.867C>T p.R289= | Silent (SNP) | VAF 47/103 reads (46%) | catalogued as rs762182367, COSV101215528; called by muse, mutect2, varscan2
- BRD1 | c.1711C>T p.L571= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV99349292; called by muse, mutect2, varscan2
- C1QTNF3 | c.720C>T p.F240= | Silent (SNP) | VAF 47/126 reads (37%) | catalogued as COSV51467777; called by muse, mutect2, varscan2
- C1orf174 | c.46T>C p.L16= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as COSV100851716; called by muse, mutect2, varscan2
- CACNA1A | c.4713C>T p.F1571= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as rs780277246, COSV64194548; called by muse, mutect2, varscan2
- CCDC170 | c.1518C>T p.L506= | Silent (SNP) | VAF 27/37 reads (73%) | catalogued as rs772924463, COSV99498118; called by muse, mutect2, varscan2
- CCR6 | c.282C>T p.L94= | Silent (SNP) | VAF 45/65 reads (69%) | catalogued as COSV100550992; called by muse, mutect2, varscan2
- CDCP1 | c.2433C>T p.P811= | Silent (SNP) | VAF 53/114 reads (46%) | catalogued as COSV99943854; called by muse, mutect2, varscan2
- CHAMP1 | c.573C>T p.V191= | Silent (SNP) | VAF 51/144 reads (35%) | catalogued as COSV100778727; called by muse, mutect2, varscan2
- CLVS1 | c.249G>A p.R83= | Silent (SNP) | VAF 28/77 reads (36%) | catalogued as rs866957503, COSV57983278; called by muse, mutect2, varscan2
- COL24A1 | c.4014G>A p.K1338= | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as rs1014800415, COSV65301114; called by muse, mutect2, varscan2
- CYP4B1 | c.813G>A p.E271= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV54724837; called by muse, mutect2, varscan2
- DNAH10 | c.4713C>T p.I1571= (on ENST00000409039; = p.I1510= on NM_207437.3) | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as rs758121229, COSV101292006, COSV101292679; called by muse, mutect2, varscan2
- DSC1 | c.267G>A p.R89= | Silent (SNP) | VAF 24/48 reads (50%) | catalogued as COSV57143423; called by muse, mutect2, varscan2
- DVL1 | c.1257C>T p.V419= (on ENST00000378888 / NM_001330311.2; = p.V394= on NM_004421.3) | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV100229277; called by muse, mutect2, varscan2
- EGFL8 | c.783G>A p.R261= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as COSV100246826; called by muse, mutect2, varscan2
- ERC2 | c.1161C>T p.I387= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as rs755705170, COSV55616908, COSV55658146; called by muse, mutect2, varscan2
- ERMAP | c.63C>T p.L21= | Silent (SNP) | VAF 28/42 reads (67%) | catalogued as rs1367764418, COSV100072115; called by muse, mutect2, varscan2
- F2RL3 | c.879G>A p.V293= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV99935082; called by muse, mutect2, varscan2
- FLT4 | c.3945C>T p.S1315= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV99986020; called by muse, mutect2, varscan2
- GALNT15 | c.978G>A p.K326= | Silent (SNP) | VAF 50/133 reads (38%) | catalogued as COSV100327292; called by muse, mutect2, varscan2
- GBP6 | c.37C>T p.L13= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV100969472; called by muse, mutect2, varscan2
- GCDH | c.891C>T p.I297= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as rs143102910; ClinVar: likely benign; called by muse, mutect2, varscan2
- GLRA2 | c.1020C>T p.F340= | Silent (SNP) | VAF 41/47 reads (87%) | catalogued as COSV54336051; called by muse, mutect2, varscan2
- GPR45 | c.966C>T p.I322= | Silent (SNP) | VAF 53/123 reads (43%) | catalogued as rs758939694, COSV51524369, COSV99306698; called by muse, mutect2, varscan2
- GRIN3A | c.1716C>T p.F572= | Silent (SNP) | VAF 41/56 reads (73%) | catalogued as rs776167297, COSV100701371; called by muse, mutect2, varscan2
- HAO2 | c.909C>T p.I303= | Silent (SNP) | VAF 31/61 reads (51%) | catalogued as COSV58042711; called by muse, mutect2, varscan2
- HEPHL1 | c.447G>A p.R149= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV59892125; called by muse, mutect2, varscan2
- HERC5 | c.2332C>T p.L778= | Silent (SNP) | VAF 33/79 reads (42%) | catalogued as COSV99987415; called by muse, mutect2, varscan2
- HNRNPH1 | c.1278C>T p.G426= | Silent (SNP) | VAF 64/129 reads (50%) | catalogued as rs769953300, COSV100270372; called by muse, mutect2, varscan2
- IGKV1-9 | c.237G>A p.G79= | Silent (SNP) | VAF 93/195 reads (48%) | catalogued as rs758789196; called by muse, mutect2, varscan2
- IGKV1D-12 | c.138G>A p.R46= | Silent (SNP) | VAF 36/135 reads (27%) | catalogued as rs374978815; called by muse, varscan2
- IGKV5-2 | c.342C>T p.F114= | Silent (SNP) | VAF 18/42 reads (43%) | called by muse, mutect2, varscan2
- IL1RAPL1 | c.1455G>A p.R485= | Silent (SNP) | VAF 43/54 reads (80%) | catalogued as COSV100145270; called by muse, mutect2, varscan2
- IMPG1 | c.351C>T p.I117= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as rs754212529, COSV100886075; called by muse, mutect2, varscan2
- IQUB | c.1953C>T p.L651= | Silent (SNP) | VAF 34/50 reads (68%) | catalogued as COSV100226771; called by muse, mutect2, varscan2
- KCNA4 | c.921G>A p.R307= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as rs779948018, COSV100068477, COSV100068583; called by muse, mutect2, varscan2
- KCNH4 | c.984C>T p.T328= | Silent (SNP) | VAF 35/96 reads (36%) | catalogued as rs769116605, COSV99236789; called by muse, mutect2, varscan2
- KCNQ2 | c.1341C>T p.P447= (on ENST00000359125 / NM_172107.4; = p.P419= on NM_004518.6) | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs1371249036, COSV100609747; called by muse, mutect2, varscan2
- KIFC1 | c.996C>T p.L332= | Silent (SNP) | VAF 49/126 reads (39%) | catalogued as COSV100997077; called by muse, mutect2, varscan2
- KLK3 | c.147C>T p.V49= | Silent (SNP) | VAF 46/114 reads (40%) | catalogued as COSV100385905; called by muse, mutect2, varscan2
- KRT79 | c.666C>T p.N222= | Silent (SNP) | VAF 52/118 reads (44%) | catalogued as rs565748878, COSV100398296, COSV100398579; called by muse, mutect2, varscan2
- KRTAP12-3 | c.174G>A p.V58= | Silent (SNP) | VAF 62/150 reads (41%) | catalogued as COSV59958597; called by muse, varscan2
- LHFPL4 | c.678G>A p.R226= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV99805062; called by muse, varscan2
- LRRC37A2 | c.3714C>T p.T1238= | Silent (SNP) | VAF 42/192 reads (22%) | catalogued as rs1301302872, COSV100238631; called by muse, mutect2, varscan2
- LRRIQ3 | c.1648C>T p.L550= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV100598507; called by muse, mutect2, varscan2
- MAPKBP1 | c.3567C>T p.P1189= (on ENST00000456763 / NM_001128608.2; = p.P1183= on NM_014994.3) | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV52964668, COSV99528959; called by muse, mutect2, varscan2
- MGA | c.5847C>T p.L1949= (on ENST00000219905 / NM_001164273.1; = p.L1740= on NM_001080541.2) | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as rs780478206, COSV99578662; called by muse, mutect2, varscan2
- MSH5 | c.1248C>T p.F416= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV100994704; called by muse, mutect2, varscan2
- MUC16 | c.8136C>T p.I2712= | Silent (SNP) | VAF 50/130 reads (38%) | catalogued as COSV101198282; called by muse, mutect2, varscan2
- MYH2 | c.471C>T p.S157= | Silent (SNP) | VAF 100/243 reads (41%) | catalogued as rs149579742, COSV55433178; called by muse, mutect2, varscan2
- MYH3 | c.2247C>T p.S749= | Silent (SNP) | VAF 36/95 reads (38%) | catalogued as rs1410478875, COSV99877757; called by muse, mutect2, varscan2
- MYH4 | c.1032C>T p.F344= | Silent (SNP) | VAF 43/87 reads (49%) | catalogued as COSV99700395, COSV99700414; called by muse, mutect2, varscan2
- MYLPF | c.48C>T p.S16= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs146541383; called by muse, mutect2, varscan2
- NFATC2 | c.258C>T p.F86= | Silent (SNP) | VAF 48/94 reads (51%) | catalogued as rs1348596949, COSV65354335; called by muse, mutect2, varscan2
- OAS2 | c.831G>A p.R277= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV100660022; called by muse, mutect2, varscan2
- OR1M1 | c.186C>T p.F62= | Silent (SNP) | VAF 45/92 reads (49%) | catalogued as rs1486635452, COSV101447543; called by muse, mutect2, varscan2
- OR2M5 | c.450C>T p.I150= | Silent (SNP) | VAF 175/510 reads (34%) | catalogued as COSV63546434; called by muse, mutect2, varscan2
- OR2T33 | c.423G>A p.R141= | Silent (SNP) | VAF 46/264 reads (17%) | catalogued as COSV100531625; called by muse, mutect2, varscan2
- OR51B2 | c.642C>T p.F214= | Silent (SNP) | VAF 19/32 reads (59%) | catalogued as rs1392447428, COSV104409841, COSV60916260; called by muse, mutect2, varscan2
- OR52M1 | c.675C>T p.F225= | Silent (SNP) | VAF 76/166 reads (46%) | catalogued as rs1310177437, COSV100798544; called by muse, mutect2, varscan2
- OR9G1 | c.600C>T p.F200= | Silent (SNP) | VAF 39/131 reads (30%) | catalogued as rs777927291, COSV56451953; called by muse, mutect2, varscan2
- OSBPL10 | c.552C>T p.S184= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs201980027, COSV101158969; called by muse, mutect2, varscan2
- OXCT1 | c.975C>T p.I325= | Silent (SNP) | VAF 37/86 reads (43%) | catalogued as COSV99541750; called by muse, mutect2, varscan2
- PANX3 | c.636G>A p.R212= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV99421244; called by muse, mutect2, varscan2
- PCDH17 | c.2727C>T p.C909= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV100931443; called by muse, mutect2, varscan2
- PCDHA7 | c.486C>T p.I162= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV65342726; called by muse, mutect2, varscan2
- PCDHA9 | c.486C>T p.I162= | Silent (SNP) | VAF 23/98 reads (23%) | catalogued as rs782110338, COSV65329555; called by muse, mutect2, varscan2
- PCDHB13 | c.531C>T p.S177= | Silent (SNP) | VAF 45/123 reads (37%) | catalogued as rs1490549848, COSV99506783; called by muse, mutect2, varscan2
- PCDHGA1 | c.864G>A p.V288= | Silent (SNP) | VAF 29/68 reads (43%) | catalogued as COSV100965931; called by muse, mutect2, varscan2
- PDGFRB | c.1314C>T p.G438= | Silent (SNP) | VAF 76/159 reads (48%) | catalogued as rs1480429176, COSV55805565; called by muse, mutect2, varscan2
- PITPNM1 | c.1560G>T p.L520= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV100711558; called by muse, mutect2, varscan2
- PLXNA3 | c.927C>T p.G309= | Silent (SNP) | VAF 65/77 reads (84%) | catalogued as rs782618267, COSV63754601; called by muse, mutect2, varscan2
- PRDM8 | c.1992G>A p.E664= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV100324933; called by muse, mutect2, varscan2
- PRUNE1 | c.1104C>T p.I368= | Silent (SNP) | VAF 22/124 reads (18%) | catalogued as COSV99639191; called by muse, mutect2, varscan2
- PTPRB | c.186C>T p.T62= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as COSV54248986; called by muse, mutect2, varscan2
- RBBP8 | c.2094C>T p.T698= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as rs1047200024, COSV59096707; called by muse, mutect2, varscan2
- RIMBP2 | c.684C>T p.F228= | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as rs766901586, COSV55473128; called by muse, mutect2, varscan2
- RNASE11 | c.498C>T p.F166= | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as COSV100250446; called by muse, mutect2, varscan2
- RNF165 | c.975C>T p.L325= | Silent (SNP) | VAF 39/103 reads (38%) | catalogued as rs138598135, COSV99491315; called by muse, mutect2, varscan2
- RP1 | c.1989G>A p.K663= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as rs372551375, CM992206, COSV99607074; called by muse, mutect2, varscan2
- SAP130 | c.3045C>T p.S1015= | Silent (SNP) | VAF 42/107 reads (39%) | catalogued as rs767117312, COSV99384133; called by muse, mutect2, varscan2
- SBNO2 | c.288C>T p.S96= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as rs1179463718, COSV100684123; called by muse, mutect2, varscan2
- SCLY | c.567C>T p.L189= (on ENST00000651534; = p.L181= on NM_016510.7) | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as rs774413830, COSV54540610; called by muse, mutect2, varscan2
- SCN5A | c.4539C>T p.P1513= (on ENST00000333535 / NM_198056.3; = p.P1512= on NM_000335.5) | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as COSV61134461; called by muse, mutect2, varscan2
- SCRN1 | c.75G>A p.G25= | Silent (SNP) | VAF 39/76 reads (51%) | catalogued as COSV54128152; called by muse, mutect2, varscan2
- SERPINB12 | c.1104G>A p.S368= | Silent (SNP) | VAF 44/120 reads (37%) | catalogued as rs148428278; called by muse, mutect2, varscan2
- SERPING1 | c.1005C>T p.F335= | Silent (SNP) | VAF 53/161 reads (33%) | catalogued as COSV53543821; called by muse, mutect2, varscan2
- SLC11A1 | c.51C>A p.S17= | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as COSV99261900; called by muse, mutect2, varscan2
- SLC6A3 | c.1791C>T p.P597= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as rs1310047234, COSV99547877; ClinVar: likely benign; called by muse, mutect2, varscan2
- SMARCAD1 | c.2484C>T p.F828= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as rs755185457, COSV62775165; called by muse, mutect2, varscan2
- SPEG | c.3615C>A p.A1205= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as rs1445235798, COSV100403366; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2868G>A p.Q956= | Silent (SNP) | VAF 29/75 reads (39%) | catalogued as COSV59136078, COSV59137471; called by muse, mutect2, varscan2
- STXBP5L | c.2163G>A p.R721= | Silent (SNP) | VAF 23/29 reads (79%) | catalogued as rs774974809, COSV56520850; called by muse, mutect2, varscan2
- TBX15 | c.753C>T p.F251= (on ENST00000369429 / NM_001330677.2; = p.F145= on NM_152380.3) | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV52874580; called by muse, mutect2, varscan2
- TRAF2 | c.315C>T p.A105= | Silent (SNP) | VAF 21/39 reads (54%) | catalogued as rs768833371, COSV56036561; called by muse, mutect2, varscan2
- TRAPPC11 | c.2832C>T p.L944= | Silent (SNP) | VAF 50/91 reads (55%) | catalogued as rs371763250; called by muse, mutect2, varscan2
- TRIM15 | c.354C>T p.F118= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as COSV100938783; called by muse, mutect2, varscan2
- TRPC3 | c.315C>T p.R105= (on ENST00000379645 / NM_001366479.2; = p.R32= on NM_003305.2) | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as rs144836583; called by muse, mutect2, varscan2
- TSBP1 | c.540G>A p.Q180= (on ENST00000617061; = p.Q190= on NM_006781.5) | Silent (SNP) | VAF 42/103 reads (41%) | catalogued as COSV100898715; called by muse, mutect2, varscan2
- TTN | c.5814C>T p.V1938= (on ENST00000591111; = p.V1892= on NM_003319.4) | Silent (SNP) | VAF 68/175 reads (39%) | catalogued as COSV59977096; called by muse, mutect2, varscan2
- UGT3A1 | c.1038G>A p.V346= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as COSV57096608, COSV57103219; called by muse, mutect2, varscan2
- VPS13D | c.1299C>T p.L433= | Silent (SNP) | VAF 71/121 reads (59%) | catalogued as COSV100692577; called by muse, mutect2, varscan2
- WDHD1 | c.2337C>T p.F779= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as COSV62212904; called by muse, mutect2, varscan2
- WDR90 | c.4680C>T p.F1560= | Silent (SNP) | VAF 32/77 reads (42%) | catalogued as COSV53475244; called by muse, mutect2
- WFDC8 | c.90C>T p.S30= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as rs1440697844, COSV99250295; called by muse, mutect2, varscan2
- WNT2 | c.816G>A p.E272= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as rs947541084, COSV55412363, COSV99625742; called by muse, mutect2, varscan2
- XIRP2 | c.7002A>C p.A2334= (on ENST00000628543; = p.A2509= on NM_152381.6) | Silent (SNP) | VAF 40/84 reads (48%) | catalogued as COSV54681339, COSV99738809; called by muse, mutect2, varscan2
- XKR6 | c.1167C>T p.F389= | Silent (SNP) | VAF 27/34 reads (79%) | catalogued as rs373676910; called by muse, mutect2, varscan2
- DCHS2 | n.8586G>A | RNA (SNP) | VAF 61/143 reads (43%) | catalogued as COSV100600918, COSV100601131; called by muse, mutect2, varscan2
- DSC1 | c.2488-122C>T | Intron (SNP) | VAF 11/43 reads (26%) | catalogued as COSV99937166; called by muse, mutect2, varscan2
- FAM153CP | chr5:178055714 C>T | 3'Flank (SNP) | VAF 42/108 reads (39%) | called by muse, mutect2
- GNAO1 | c.723+6979G>A | Intron (SNP) | VAF 16/43 reads (37%) | catalogued as COSV99340721; called by muse, mutect2
- ISCA1P1 | n.258C>T | RNA (SNP) | VAF 84/183 reads (46%) | catalogued as rs1205783599; called by muse, mutect2, varscan2
- MAP3K19 | c.3222+486G>A | Intron (SNP) | VAF 35/74 reads (47%) | catalogued as rs1333059931, COSV59637965; called by muse, mutect2, varscan2
- NACA | c.71-4181C>T | Intron (SNP) | VAF 12/41 reads (29%) | catalogued as COSV100771086; called by muse, mutect2, varscan2
- PLCB1 | c.2524-6233C>T | Intron (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- ST8SIA2 | chr15:92473072 G>A | 3'Flank (SNP) | VAF 29/69 reads (42%) | called by muse, mutect2, varscan2
